Gene-level copy-number profile of tumor specimen HCM-BROD-0483-C16-07A from HCMI case HCM-BROD-0483-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 50.1 years (18,303 days).
Specimen HCM-BROD-0483-C16-07A: Sample type: Additional Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 69505d03-71c0-4da8-b7fb-72228689fcbc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0483-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/6d170cc9-3433-42e6-ac26-f699d8eebac3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,527; copy number 2: 10,291; copy number 3: 21,197; copy number 4: 20,989; copy number 5: 2,829; copy number 6: 747; copy number 7: 220; copy number 8: 62; copy number 9: 23; copy number 10: 95; copy number 11: 8; copy number 13: 23; copy number 14: 153; copy number 15: 163; copy number 20: 2; copy number 31: 3; copy number 35: 11; copy number 40: 40; copy number 44: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:111,394,875–111,411,883, 2 genes (within-gene range 0–4): AC003989.2, AC003989.1.
- chr10:17,137,336–17,237,593, 4 genes (within-gene range 0–1): TRDMT1, VIM-AS1, VIM, AL133415.1.
- chr17:18,453,574–18,506,313, 4 genes: AL353997.4, TNPO1P2, LGALS9C, NOS2P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 522 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:79,768,028–80,226,181, 1 gene, copy number 15 (within-gene range 5–15): GNAI1.
- chr7:80,096,600–83,362,266, 26 genes, copy number 10–15: RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1.
- chr7:84,528,122–100,906,572, 321 genes, copy number 13–15 (broad region; genes not listed).
- chr7:107,765,467–108,721,601, 14 genes, copy number 15–44: SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1.
- chr7:116,275,606–117,883,675, 45 genes, copy number 20–40 (within-gene range 20–49): AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1.
- chr10:23,694,746–24,723,887, 8 genes, copy number 11 (within-gene range 2–11): KIAA1217, NUP35P1, AC063961.1, MIR603, AL356113.1, AL353583.1, ARHGAP21, RNA5SP305.
- chr17:34,980,512–35,377,678, 22 genes, copy number 9 (within-gene range 5–9): LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault, FNDC8, NLE1, UNC45B, AC022916.4, AC022916.2, AC022916.3, SLC35G3, AC022916.1, SLFN5, AC022706.1, AC060766.2, SLFN11, AC060766.3.
- chr17:37,084,992–39,402,523, 84 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr20:30,214,765–30,214,976, 1 gene, copy number 9: CFTRP3.

Autosomal genes at a single copy (total copy number 1): 1,527. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
